Somatic mutation profile of tumor specimen TCGA-CR-7376-01A (aliquot TCGA-CR-7376-01A-11D-2129-08) from TCGA case TCGA-CR-7376, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 84.0 years (30,670 days).
Specimen TCGA-CR-7376-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f86aea9e-79b8-46f2-a43a-055d0b032021.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7376-10A (Blood Derived Normal), aliquot TCGA-CR-7376-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ac6c952-e882-4c6e-b51c-9b28f07083b8

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 4, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.840A>C p.R280S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1567547687, CM136794, COSV52678283, COSV52782181, COSV52801834, COSV53205654; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.96_96+1dup p.X32_splice | Splice Site (INS) | VAF 7/50 reads (14%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AKAP9 | c.5531C>G p.S1844* (on ENST00000359028; = p.S1812* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100662148; called by muse, mutect2, varscan2
- ANO6 | c.1273C>G p.R425G | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV100262663; called by muse, mutect2
- ARMC4 | c.2036T>C p.V679A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100536516; called by muse, mutect2
- ASXL3 | c.6493A>C p.K2165Q | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV99323563, COSV99323996; called by muse, mutect2
- C8orf34 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as COSV61377330; called by muse, mutect2
- CAPRIN2 | c.2227C>G p.Q743E | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV99195451; called by muse, mutect2
- CCDC88C | c.2142G>C p.E714D | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV101105360, COSV66242717; called by muse, mutect2
- CRY1 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99150516; called by muse, mutect2
- CRYBG1 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV64811158, COSV64812480; called by muse, mutect2, varscan2
- DCP1B | c.175T>A p.L59I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99767355; called by muse, mutect2
- DPEP1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99878376; called by muse, mutect2, varscan2
- EFCAB14 | c.1301C>G p.S434C | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100905565; called by muse, mutect2
- ELF4 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); catalogued as rs756574054, COSV100257251; called by muse, mutect2, varscan2
- GLRA2 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54344392, COSV99490558; called by muse, mutect2, varscan2
- HCN2 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as rs1362207541, COSV99241470, COSV99242078; called by muse, varscan2
- HEATR5A | c.5098C>T p.L1700F | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs532581649, COSV101119760; called by muse, mutect2, varscan2
- HPR | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as rs374484725; called by muse, mutect2, varscan2
- IGHV3-7 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs528253327; called by muse, mutect2
- LAMB1 | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs267601228, COSV55963509; called by muse, mutect2, varscan2
- LAMTOR1 | c.446A>T p.D149V | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99194388; called by muse, mutect2
- LRMDA | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as rs200848450; called by muse, mutect2, varscan2
- MOB2 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100326476; called by muse, mutect2, varscan2
- MTPAP | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99553911; called by muse, mutect2
- NOTCH1 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53041388, COSV53082575; called by muse, mutect2
- OR2J2 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV65847997, COSV65848230; called by muse, mutect2
- OR6B1 | c.796T>G p.F266V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV101281640; called by muse, mutect2
- PCDHGA12 | c.1951C>A p.Q651K | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV99338880; called by muse, mutect2
- PRKAG2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs755301694, COSV99834978; called by muse, mutect2
- RABGEF1 | c.657G>C p.K219N (on ENST00000439720 / NM_001287061.2; = p.K206N on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV99534622; called by muse, mutect2
- RBBP7 | c.1025A>C p.N342T | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.136); catalogued as COSV100417840; called by muse, mutect2, varscan2
- RNF40 | c.1020G>C p.E340D | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100221960; called by muse, mutect2
- SLC22A14 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99828154; called by muse, mutect2, varscan2
- TGFBR2 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV55448334; called by muse, mutect2, varscan2
- TMEM25 | c.913A>T p.N305Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100244733; called by muse, mutect2, varscan2
- TRIO | c.8578G>C p.E2860Q | Missense Mutation (SNP) | VAF 9/285 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99073232; called by muse, mutect2
- TTN | c.66331G>A p.E22111K (on ENST00000591111; = p.E14687K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | PolyPhen benign (0.015); catalogued as COSV100618220, COSV60165529; called by muse, mutect2, varscan2
- IGKV2-30 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- RCC2 | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- A2M | c.1818C>T p.L606= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1480635604, COSV100588547; called by muse, mutect2
- ABLIM3 | c.1197C>T p.Y399= | Silent (SNP) | VAF 13/152 reads (9%) | called by muse, mutect2
- ACOX2 | c.1041C>G p.L347= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100250070; called by muse, mutect2
- GNE | c.783A>T p.I261= (on ENST00000396594 / NM_001128227.3; = p.I230= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV100929898, COSV100929912; called by muse, mutect2
- GPR15 | c.135G>T p.L45= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV99423679; called by muse, mutect2
- KLK12 | c.699T>C p.Y233= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as rs1004897692, COSV51577488, COSV99141843; called by muse, mutect2, varscan2
- MPL | c.1242G>A p.S414= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs544064034, COSV65244840; called by muse, mutect2
- MUC6 | c.4434A>T p.S1478= | Silent (SNP) | VAF 22/251 reads (9%) | catalogued as COSV101424465; called by muse, mutect2
- PCOLCE | c.1218G>A p.E406= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV56159056, COSV99774902; called by muse, mutect2, varscan2
- PRAMEF2 | c.777C>T p.F259= | Silent (SNP) | VAF 12/155 reads (8%) | catalogued as rs529323357, COSV53577332; called by muse, mutect2
- PREX2 | c.2352T>C p.F784= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV99905923; called by muse, mutect2
- PXDN | c.3525C>G p.V1175= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as rs1266215713, COSV99412781; called by muse, mutect2
- SLC4A9 | c.2274C>G p.L758= (on ENST00000507527 / NM_001258428.2; = p.L734= on NM_031467.3) | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99138573; called by muse, mutect2
- SSX6P | n.276C>A | RNA (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
